Somatic mutation profile of tumor specimen ALCH-B1MP-TTP1-A (aliquot ALCH-B1MP-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1MP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.0 years (29,223 days).
Specimen ALCH-B1MP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71b3203e-20b0-4a18-aaed-afc88aa45a41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1MP-NB1-A (Blood Derived Normal), aliquot ALCH-B1MP-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65145183-8db1-4ec2-8a45-d7d98fea3012

The open-access MAF lists 44 somatic variants for this specimen: 28 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 15, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 129/762 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AUTS2 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 74/323 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs369919917; called by muse, mutect2, varscan2
- COL4A1 | c.4282G>A p.D1428N | Missense Mutation (SNP) | VAF 46/894 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.661); catalogued as rs747393485; called by muse, mutect2
- DCAF8L1 | c.1092G>C p.Q364H | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV71595337; called by muse, mutect2, varscan2
- HABP4 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.207); catalogued as rs1486938648; called by muse, mutect2, varscan2
- HYAL2 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427733825; called by muse, mutect2
- IGKV1D-13 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 112/775 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs777852760; called by muse, mutect2, varscan2
- LYZL1 | c.340G>A p.G114S (on ENST00000375500; = p.G68S on NM_032517.6) | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1478095604; called by muse, mutect2, varscan2
- PDZD2 | c.6872C>T p.P2291L | Missense Mutation (SNP) | VAF 104/339 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs1200633932; called by muse, mutect2, varscan2
- PLG | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 104/643 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs371746732, COSV51981567; called by muse, mutect2, varscan2
- TERB1 | c.2180C>A p.S727Y | Missense Mutation (SNP) | VAF 17/566 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV50754111, COSV50756017; called by muse, mutect2
- ANKRD24 | c.3030G>T p.K1010N | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPPA2 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 162/385 reads (42%) | called by muse, mutect2, varscan2
- ENTHD1 | c.1508dup p.N504Efs*7 | Frame Shift Ins (INS) | VAF 36/374 reads (10%) | called by mutect2, pindel
- FRY | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 82/483 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- GNAI1 | c.888T>A p.Y296* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2
- GOLGA8M | c.1464C>A p.C488* | Nonsense Mutation (SNP) | VAF 64/1098 reads (6%) | called by muse, mutect2
- IGLV2-18 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 142/827 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGSF3 | c.3524A>G p.N1175S (on ENST00000369486 / NM_001007237.3; = p.N1195S on NM_001542.4) | Missense Mutation (SNP) | VAF 92/559 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAP3K1 | c.3386A>T p.N1129I | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PGK1 | c.164C>G p.A55G | Missense Mutation (SNP) | VAF 117/752 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PTEN | c.867dup p.V290Sfs*8 | Frame Shift Ins (INS) | VAF 73/437 reads (17%) | called by mutect2, pindel, varscan2
- RP1L1 | c.3615C>A p.S1205R | Missense Mutation (SNP) | VAF 109/611 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RPS28 | c.88-2A>G p.X30_splice | Splice Site (SNP) | VAF 22/398 reads (6%) | called by muse, mutect2
- SERGEF | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 68/552 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SHOC1 | c.77C>A p.T26K | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2
- TRAF3IP3 | c.1569A>T p.Q523H | Missense Mutation (SNP) | VAF 31/518 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); called by muse, mutect2
- USP4 | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARFGEF1 | c.291T>C p.S97= | Silent (SNP) | VAF 48/208 reads (23%) | called by muse, mutect2
- CENPC | c.1803A>C p.G601= | Silent (SNP) | VAF 97/531 reads (18%) | called by muse, mutect2, varscan2
- EPYC | c.850T>C p.L284= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs1252313880; called by muse, mutect2, varscan2
- MARK1 | c.2259G>A p.V753= | Silent (SNP) | VAF 85/643 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.36210C>T p.V12070= | Silent (SNP) | VAF 43/269 reads (16%) | catalogued as rs771354734; called by muse, mutect2, varscan2
- NEK4 | c.735G>A p.R245= | Silent (SNP) | VAF 19/432 reads (4%) | catalogued as rs751881145; called by muse, mutect2
- NLRP8 | c.1395G>A p.R465= | Silent (SNP) | VAF 37/524 reads (7%) | called by muse, mutect2
- NR1D1 | c.708G>A p.P236= | Silent (SNP) | VAF 62/303 reads (20%) | catalogued as rs147503529; called by muse, mutect2, varscan2
- OR6T1 | c.609T>C p.S203= | Silent (SNP) | VAF 62/752 reads (8%) | called by muse, mutect2
- SFT2D3 | c.579C>A p.G193= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- SYT7 | c.894C>T p.I298= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as rs745552660, COSV55657283; called by muse, mutect2
- TEX10 | c.1275C>T p.S425= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- TLR7 | c.1026C>A p.L342= | Silent (SNP) | VAF 57/287 reads (20%) | called by muse, mutect2, varscan2
- USP4 | c.1920C>T p.G640= | Silent (SNP) | VAF 32/237 reads (14%) | called by muse, mutect2, varscan2
- ZNF217 | c.1923T>C p.C641= | Silent (SNP) | VAF 86/517 reads (17%) | called by muse, mutect2, varscan2
- SYNJ2 | c.214+454T>C | Intron (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
